CPTAC case GTEX-Y8DK-0011-R10A-SM-HAKY1 — Brain (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/26d9cf48-feb1-4bfc-a983-0a03861b1b45

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Dead; Days to death: 0 days.

Exposures
- Alcohol history: No.

Biospecimens (1 sample)
- Sample PT-Y8DK-01: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2.
